CCDI case PBCGVH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cf64fd58-d20c-4305-8fd8-afb8eabf23e7

Demographics
Sex at birth: female.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.9 years (337 days).

Biospecimens (3 samples)
- Sample 0DRQSN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRQSZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRQT8: Tissue type: Tumor; Specimen type: Solid Tissue.
